Somatic mutation profile of tumor specimen TCGA-J9-A52B-01A (aliquot TCGA-J9-A52B-01A-11D-A26M-08) from TCGA case TCGA-J9-A52B, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.6 years (22,849 days).
Specimen TCGA-J9-A52B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 679dc37a-68b5-4866-ac4b-d78280a529b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J9-A52B-10A (Blood Derived Normal), aliquot TCGA-J9-A52B-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9bb6aea-1c35-488e-9c12-ce009e386032

The open-access MAF lists 33 somatic variants for this specimen: 32 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 22, Nonsense Mutation 5, Splice Site 2, Frame Shift Del 2, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376-15_382del p.X126_splice | Splice Site (DEL) | VAF 10/30 reads (33%) | hotspot (GDC flag); called by mutect2, varscan2
- AGPAT4 | c.918G>C p.W306C | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57252469; called by muse, mutect2, varscan2
- ANKRD30A | c.733G>T p.A245S (on ENST00000611781; = p.A189S on NM_052997.2) | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV64623819; called by muse, mutect2, varscan2
- ATF4 | c.406del p.Q136Rfs*3 | Frame Shift Del (DEL) | VAF 117/384 reads (30%) | catalogued as rs770192882; called by mutect2, pindel, varscan2
- CHD3 | c.5179G>T p.E1727* (on ENST00000330494 / NM_001005273.3; = p.E1693* on NM_005852.4) | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV57881468; called by muse, mutect2, varscan2
- DCAF12L1 | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV64422994; called by muse, mutect2, varscan2
- DLL3 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs1431230159, COSV52694604; called by muse, mutect2, varscan2
- DRD3 | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as COSV55683402; called by muse, mutect2
- FAM83G | c.2107G>T p.V703F | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as rs1225807334, COSV58763055; called by muse, mutect2, varscan2
- FAT3 | c.10612C>T p.R3538C | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as rs935630399, COSV53187636; called by muse, mutect2
- GPR18 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs754297101, COSV61621574; called by muse, mutect2, varscan2
- LINGO1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.013); catalogued as rs1051425842, COSV62439006; called by muse, mutect2, varscan2
- LRRIQ3 | c.103T>G p.F35V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV63051299; called by muse, mutect2
- LYSMD4 | c.523C>T p.Q175* (on ENST00000409796 / NM_001284417.2; = p.Q176* on NM_152449.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/143 reads (27%) | catalogued as COSV60387895; called by muse, mutect2, varscan2
- MAST1 | c.266G>C p.W89S | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52256882, COSV99263097; called by muse, mutect2, varscan2
- MMS22L | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763945699, COSV51528034; called by muse, mutect2, varscan2
- MTTP | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs746203182, COSV55508172, COSV55510680; called by muse, mutect2, varscan2
- MYH10 | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52613599; called by muse, mutect2, varscan2
- OBSCN | c.3602A>G p.K1201R | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.113); catalogued as COSV52842488; called by muse, mutect2, varscan2
- PCDHB3 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.022); catalogued as rs138158842; called by muse, mutect2, varscan2
- PEX2 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as COSV63814439; called by muse, mutect2, varscan2
- PLPP1 | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV53308746; called by muse, mutect2
- RFXAP | c.711G>A p.S237= | Splice Region (SNP) | VAF 9/49 reads (18%) | catalogued as rs760354012, COSV55226556; ClinVar: likely benign; called by muse, mutect2, varscan2
- SESN2 | c.674G>T p.S225I | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as COSV53429890; called by muse, mutect2
- SRCAP | c.6157C>T p.R2053W | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs371915992; called by muse, varscan2
- SVEP1 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV57028594, COSV57050454; called by muse, mutect2, varscan2
- SYNE1 | c.14818A>C p.I4940L (on ENST00000367255 / NM_182961.4; = p.I4869L on NM_033071.3) | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.163); catalogued as COSV55129032; called by muse, mutect2, varscan2
- TCF20 | c.2831A>T p.N944I | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as COSV59496980; called by muse, mutect2, varscan2
- TNFRSF13B | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV55431134; called by muse, mutect2, varscan2
- ANKRD37 | c.180+2dup p.X60_splice | Splice Site (INS) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- IGKV1D-43 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PLIN3 | c.521_522del p.Q174Lfs*48 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | called by mutect2, pindel, varscan2
- SLC45A1 | c.1149C>T p.G383= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs368992612; called by muse, mutect2, varscan2
